Gene-level copy-number profile of tumor specimen HCM-WCMC-0786-C34-01A from HCMI case HCM-WCMC-0786-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 76.8 years (28,050 days).
Specimen HCM-WCMC-0786-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 81b45139-6048-41f8-82f7-f2d1ae705994.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0786-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/0d7934b7-ba3f-4d8d-935e-9c37718554ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 5,105; copy number 2: 50,201; copy number 3: 3,482; copy number 4: 2; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,526,597, 4 genes: PLCH2, AL139246.1, AL139246.4, PANK4.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:40,767,870–40,883,763, 2 genes: AL353626.1, AL353626.2.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:106,524–111,850, 1 gene (within-gene range 0–1): AC026369.3.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:25,056,860–25,091,877, 22 genes (within-gene range 0–2): SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15, SNORD116-16, SNORD116-17, SNORD116-18, SNORD116-19, AC124312.3, SNORD116-20, SNORD116-21, SNORD116-22, SNORD116-23.
- chr15:25,091,960–25,257,027, 56 genes (within-gene range 0–2): AC124312.4, SNORD116-24, SNORD116-25, SNORD116-26, SNORD116-27, SNORD116-28, SNORD116-29, SNORD116-30, PWAR1, SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–1): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr20:63,942,631–63,956,985, 2 genes (within-gene range 0–1): MIR647, UCKL1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:64,654,060–64,655,019, 1 gene, copy number 5: AC078962.3.

Autosomal genes at a single copy (total copy number 1): 2,259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
